Somatic mutation profile of tumor specimen TCGA-BS-A0UA-01A (aliquot TCGA-BS-A0UA-01A-11D-A122-09) from TCGA case TCGA-BS-A0UA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 68.1 years (24,872 days).
Specimen TCGA-BS-A0UA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a67f2ba5-1e61-4d41-b71c-dbee249bbb50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0UA-10A (Blood Derived Normal), aliquot TCGA-BS-A0UA-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64566b8d-4a10-45c6-a98f-85adfceccba6

The open-access MAF lists 400 somatic variants for this specimen: 306 protein-altering or splice-affecting, 88 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 191, Silent 88, Frame Shift Del 67, Nonsense Mutation 23, Frame Shift Ins 15, Splice Region 5, In Frame Del 3, RNA 2, Intron 2, Splice Site 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CAPN3 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557164942, CM053158, CM990316, COSV100520629, COSV58826533; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FREM2 | c.2206C>T p.R736* | Nonsense Mutation (SNP) | VAF 24/98 reads (24%) | catalogued as rs939534674, COSV54826565, COSV99748664; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACBD4 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs765863543, COSV58853553; called by muse, mutect2, varscan2
- ACVR1B | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as rs769120851, COSV57780540; called by muse, mutect2, varscan2
- ACVR1B | c.1451G>T p.R484L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57776372, COSV57780549; called by muse, mutect2, varscan2
- ADAMTS16 | c.1586G>A p.C529Y | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772834569, COSV57007646; called by muse, mutect2, varscan2
- AGL | c.1874C>A p.T625K | Missense Mutation (SNP) | VAF 175/688 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54059039; called by muse, mutect2, varscan2
- AGO2 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV55046708; called by muse, mutect2, varscan2
- AKAP12 | c.4935G>T p.E1645D | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV53582389; called by muse, mutect2, varscan2
- ALDH1A1 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as COSV99920939; called by muse, mutect2
- ALKBH2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs754348754, COSV57449541, COSV57451664; called by muse, varscan2
- ALMS1 | c.11762A>C p.E3921A | Missense Mutation (SNP) | VAF 104/401 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV52522456; called by muse, mutect2, varscan2
- ALOX15B | c.1943C>A p.S648* | Nonsense Mutation (SNP) | VAF 40/184 reads (22%) | catalogued as COSV101205546; called by muse, mutect2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 35/139 reads (25%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKK1 | c.1096del p.L366Sfs*13 | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | catalogued as rs755428982; called by mutect2, pindel, varscan2
- ANKRD50 | c.3055G>A p.A1019T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV72386337; called by muse, mutect2, varscan2
- AP2A2 | c.170dup p.Y58Vfs*14 | Frame Shift Ins (INS) | VAF 50/236 reads (21%) | catalogued as rs753029866; called by mutect2, varscan2
- ARID1A | c.6762C>G p.Y2254* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV61373199, COSV61374456; called by muse, mutect2, varscan2
- ARPP21 | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 56/245 reads (23%) | catalogued as COSV51808612; called by muse, mutect2, varscan2
- ASB9 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.593); catalogued as COSV100995358; called by muse, mutect2
- ASH2L | c.947G>T p.S316I | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV99166906; called by muse, mutect2
- ASXL3 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs765803411, COSV52471978, COSV52475965, COSV99324572; called by muse, mutect2, varscan2
- ATR | c.3402dup p.N1135* | Frame Shift Ins (INS) | VAF 78/324 reads (24%) | catalogued as rs1043355995; called by mutect2, varscan2
- BICDL1 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.279); catalogued as rs368184092; called by muse, mutect2, varscan2
- BRWD3 | c.2673G>T p.L891F | Missense Mutation (SNP) | VAF 184/792 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as COSV64753843; called by muse, mutect2, varscan2
- C1QTNF4 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs866041290, COSV100209144; called by muse, mutect2, varscan2
- C2orf73 | c.671G>A p.C224Y | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58312116; called by muse, mutect2, varscan2
- C3AR1 | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 48/209 reads (23%) | catalogued as COSV50822990, COSV50825115; called by muse, mutect2, varscan2
- CABP4 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs373263875; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1G | c.6948del p.E2317Rfs*47 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs766047428; called by mutect2, pindel, varscan2
- CACNA1S | c.4166G>A p.R1389Q | Missense Mutation (SNP) | VAF 77/317 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs756438139, COSV62938076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPRIN2 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 86/335 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV51835602; called by muse, mutect2, varscan2
- CBFA2T2 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV60076008; called by muse, mutect2, varscan2
- CCDC138 | c.1695A>T p.K565N | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV54572025; called by muse, mutect2, varscan2
- CCNL1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 116/470 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs773357422, COSV55818496, COSV55819453; called by muse, mutect2, varscan2
- CFAP300 | c.257G>T p.W86L | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV71570992; called by muse, mutect2, varscan2
- CFAP65 | c.2723G>A p.R908H | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs746043657, COSV58564079; called by muse, mutect2, varscan2
- CFAP97 | c.306del p.K102Nfs*23 | Frame Shift Del (DEL) | VAF 122/508 reads (24%) | catalogued as rs1305639008; called by mutect2, varscan2
- CHD3 | c.3628C>T p.R1210W | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775581978, COSV57880550; called by muse, mutect2, varscan2
- CHST5 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV60341692; called by muse, mutect2, varscan2
- CIC | c.3743del p.P1248Hfs*54 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | catalogued as COSV50671496; called by mutect2, varscan2
- CLIP2 | c.2565G>A p.A855= | Splice Region (SNP) | VAF 8/25 reads (32%) | catalogued as rs782562882, COSV56286526; called by muse, mutect2, varscan2
- CNTN3 | c.2359G>T p.G787* | Nonsense Mutation (SNP) | VAF 90/387 reads (23%) | catalogued as COSV55175977; called by muse, mutect2, varscan2
- CNTNAP5 | c.719T>A p.L240Q | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70512905; called by muse, mutect2, varscan2
- COL13A1 | c.1102G>T p.G368W (on ENST00000398978 / NM_001130103.2; = p.G311W on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62570480; called by muse, mutect2, varscan2
- COPB1 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 89/353 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.098); catalogued as COSV51450938; called by muse, mutect2, varscan2
- CREB3L3 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs775653860, CM115361, COSV50275820; called by muse, mutect2, varscan2
- CROCC | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1235070682, COSV65014976; called by muse, varscan2
- CRX | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs371847743, CM128839, COSV55759532; called by muse, mutect2, varscan2
- CSMD2 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs765855031, COSV53907870; called by muse, mutect2, varscan2
- CTNND1 | c.2458C>T p.R820* (on ENST00000399050 / NM_001085458.2; = p.R814* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 53/200 reads (27%) | catalogued as COSV62382612; called by muse, mutect2, varscan2
- CUX1 | c.3634C>T p.R1212W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52909305; called by muse, mutect2
- CWC25 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770716552; called by muse, mutect2, varscan2
- CYTL1 | c.153G>A p.S51= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as COSV57038290; called by muse, mutect2, varscan2
- DCAF1 | c.2114G>A p.G705D | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV60046767; called by muse, mutect2, varscan2
- DCAF12L2 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100758422; called by muse, mutect2
- DCAF8 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as COSV58786022; called by muse, mutect2, varscan2
- DDX19A | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 116/543 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV56361388; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs553532837; called by mutect2, varscan2
- DLK1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as rs761957781, COSV100374981; called by muse, mutect2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | catalogued as rs751671358; called by mutect2, varscan2
- DOCK6 | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs764331027, COSV52949759; called by muse, mutect2, varscan2
- DQX1 | c.365C>G p.T122S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV57818872; called by muse, mutect2, varscan2
- E2F1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs864622017, COSV58534885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- E4F1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57041440; called by muse, mutect2, varscan2
- EFHC2 | c.1314dup p.A439Cfs*10 | Frame Shift Ins (INS) | VAF 57/265 reads (22%) | catalogued as rs752671785; called by mutect2, varscan2
- EHD4 | c.1190T>C p.M397T | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs1373510938, COSV55007212; called by muse, mutect2, varscan2
- EMSY | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 75/287 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as rs534551359, COSV58266149; called by muse, mutect2, varscan2
- ENTPD7 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs374494342; called by muse, mutect2, varscan2
- EPHB2 | c.515G>A p.S172N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1436755607, COSV65864430; called by muse, mutect2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 52/221 reads (24%) | catalogued as rs768793415; called by mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 35/77 reads (45%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 121/472 reads (26%) | catalogued as rs753821453; called by mutect2, varscan2
- ESCO1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 33/544 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs148166176; called by muse, mutect2
- ETV6 | c.195C>A p.D65E | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67154424; called by muse, mutect2, varscan2
- EXOC2 | c.2450C>T p.S817F | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV57864900, COSV57872057; called by muse, mutect2, varscan2
- FASTKD5 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs781016406, COSV53909887; called by muse, mutect2, varscan2
- FAT3 | c.1042A>G p.K348E | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV99960025; called by muse, mutect2
- FAT4 | c.2777G>A p.G926D | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67900753; called by muse, mutect2, varscan2
- FBN3 | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1316444521, COSV54473497; called by muse, mutect2, varscan2
- FCGBP | c.6097C>A p.R2033S | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.13); catalogued as COSV55455508; called by muse, mutect2
- FER1L6 | c.3067G>T p.G1023* | Nonsense Mutation (SNP) | VAF 76/318 reads (24%) | catalogued as COSV101205738, COSV67552892; called by muse, mutect2, varscan2
- FERD3L | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51762208; called by muse, mutect2, varscan2
- FHOD1 | c.1237G>T p.G413C | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV50761800, COSV50770541; called by muse, mutect2, varscan2
- FLNA | c.5491C>T p.R1831W (on ENST00000369850 / NM_001110556.2; = p.R1823W on NM_001456.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1260834543, COSV61052227; called by muse, mutect2, varscan2
- FNDC1 | c.3040C>A p.Q1014K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV51948043; called by muse, mutect2, varscan2
- FOXRED2 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99340621; called by muse, mutect2
- FREM1 | c.6109G>A p.A2037T | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs201502030; called by muse, mutect2, varscan2
- GORASP1 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs746306013, COSV56534526; called by muse, mutect2, varscan2
- GPAA1 | c.989A>T p.Y330F | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs782085518, COSV60156551; called by muse, mutect2, varscan2
- GPR15 | c.572T>A p.I191N | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV52521493; called by muse, mutect2, varscan2
- GREB1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs758239737, COSV52182375; called by muse, mutect2, varscan2
- GRIK4 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs556909844, COSV70804162; called by muse, mutect2, varscan2
- GRIN3A | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs962619066, COSV62452826; called by muse, mutect2, varscan2
- GRN | c.1590C>A p.N530K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as COSV50009195; called by muse, mutect2, varscan2
- GSTO1 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 166/695 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV58539794; called by muse, mutect2, varscan2
- GTPBP8 | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV55607612; called by muse, mutect2, varscan2
- H2AZ2 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as CM161440, COSV56062462, COSV56063158; called by muse, mutect2, varscan2
- HARS1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 116/525 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs550778711, COSV56905701; called by muse, mutect2, varscan2
- HGS | c.1810A>G p.M604V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs373217884; called by mutect2, varscan2
- HIKESHI | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 153/288 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759061923, COSV53575860; called by muse, mutect2, varscan2
- HNRNPM | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); catalogued as rs753670215, COSV55317217; called by muse, mutect2, varscan2
- HSPG2 | c.6058G>A p.A2020T | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs554214201, COSV65977508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTN1 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 159/698 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs1186578606, COSV55895577; called by muse, mutect2, varscan2
- HYDIN | c.3800A>G p.D1267G | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV66834460; called by muse, mutect2, varscan2
- IGFBP2 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922678795, COSV52081460; called by muse, mutect2, varscan2
- IGFN1 | c.1820G>A p.R607Q (on ENST00000295591 / NM_001367841.1; = p.R3064Q on NM_001164586.2) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.23); catalogued as rs148033484, COSV55167675; called by muse, mutect2, varscan2
- IGHV4-31 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 84/460 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as rs1347220592, rs539394316; called by muse, varscan2
- IL17RB | c.501G>T p.M167I | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV55474487; called by muse, mutect2, varscan2
- IL9R | c.976T>G p.W326G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV54902322; called by muse, mutect2, varscan2
- IRF2BP1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV56195187; called by muse, mutect2, varscan2
- ITPR1 | c.7963G>A p.E2655K (on ENST00000354582; = p.E2600K on NM_002222.7) | Missense Mutation (SNP) | VAF 84/329 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV56978849; called by muse, mutect2, varscan2
- KCNH2 | c.3400C>T p.R1134* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as rs965259777, CD057243, COSV51230175; called by muse, mutect2, varscan2
- KCNMB3 | c.389T>C p.V130A | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55999852; called by muse, mutect2, varscan2
- KCNQ2 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1233641462, COSV60432266; called by muse, mutect2, varscan2
- KIAA0895 | c.1489C>T p.R497* (on ENST00000297063 / NM_001100425.2; = p.R446* on NM_015314.3) | Nonsense Mutation (SNP) | VAF 28/474 reads (6%) | catalogued as rs781346763, COSV99766386; called by muse, mutect2
- KITLG | c.493G>T p.V165F | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV57204143; called by muse, mutect2, varscan2
- KLF17 | c.1156G>C p.A386P | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as COSV64856255; called by muse, mutect2, varscan2
- KLHDC7A | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.019); catalogued as rs375552768, COSV68769225; called by muse, mutect2
- KLHL17 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.419); catalogued as rs1233603974, COSV58533668; called by muse, mutect2, varscan2
- KMT2D | c.7708C>A p.P2570T | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV56487943; called by muse, mutect2, varscan2
- KRT84 | c.448del p.L150Sfs*12 | Frame Shift Del (DEL) | VAF 53/250 reads (21%) | catalogued as rs760271215, COSV57771546; called by mutect2, pindel, varscan2
- LARP1 | c.2002C>T p.R668C (on ENST00000518297 / NM_033551.3; = p.R591C on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs780785993, COSV100303308; called by muse, mutect2
- LENG8 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58730619; called by muse, mutect2, varscan2
- LGALS9 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 71/256 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56351443; called by muse, mutect2, varscan2
- LOXL2 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs780665877, COSV66691463; called by mutect2, varscan2
- LRIG3 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772953918, COSV57867902; called by muse, mutect2, varscan2
- LYZL2 | c.383G>A p.W128* (on ENST00000375318; = p.W82* on NM_183058.3) | Nonsense Mutation (SNP) | VAF 62/256 reads (24%) | catalogued as COSV64684025; called by muse, varscan2
- MAN2B1 | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 86/334 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.759); catalogued as rs767192781, COSV55473438; called by muse, varscan2
- MAP2K1 | c.980G>C p.S327T | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV57235392; called by muse, mutect2, varscan2
- MAP3K1 | c.1850del p.G617Efs*39 | Frame Shift Del (DEL) | VAF 30/153 reads (20%) | catalogued as CM108514; called by mutect2, pindel, varscan2
- MAPK8IP3 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs777499600, COSV51727553; called by muse, mutect2, varscan2
- MAPRE3 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as rs749554114, COSV51869389; called by muse, mutect2, varscan2
- MAT1A | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as rs766735917, COSV64747123; called by muse, mutect2, varscan2
- MC5R | c.698G>A p.S233N | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as COSV61255800; called by muse, mutect2, varscan2
- MCM5 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.889); catalogued as rs751790568, COSV53345100; called by muse, mutect2, varscan2
- ME3 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as rs559249904, COSV62775257; called by muse, mutect2, varscan2
- ME3 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781575740, COSV100042391, COSV60165771; called by muse, mutect2, varscan2
- MED25 | c.957del p.F320Sfs*57 | Frame Shift Del (DEL) | VAF 48/186 reads (26%) | catalogued as COSV57206963; called by mutect2, pindel, varscan2
- MEGF6 | c.4318del p.A1440Hfs*78 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs759225724, COSV53895347; called by mutect2, pindel, varscan2
- MKRN3 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as rs767507343, COSV58812296; called by muse, mutect2, varscan2
- MOAP1 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs774501324, COSV52093604; called by muse, mutect2, varscan2
- MPI | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566620411, CM002365, COSV60397024; called by muse, mutect2, varscan2
- MSANTD2 | c.1030C>T p.R344* (on ENST00000374979 / NM_001308027.2; = p.R292* on NM_024631.4) | Nonsense Mutation (SNP) | VAF 48/175 reads (27%) | catalogued as COSV53451329; called by muse, mutect2, varscan2
- MUC17 | c.9575G>A p.S3192N | Missense Mutation (SNP) | VAF 114/511 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV60303933; called by muse, mutect2, varscan2
- MUC2 | c.2926G>A p.V976M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs368990528; called by muse, mutect2, varscan2
- MYB | c.769A>G p.S257G | Missense Mutation (SNP) | VAF 148/574 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100214681, COSV57201940; called by muse, mutect2, varscan2
- MYZAP | c.1382T>C p.M461T (on ENST00000267853 / NM_001018100.5; = p.M433T on NM_152451.7) | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51099059; called by muse, mutect2, varscan2
- N4BP2 | c.3526G>A p.V1176M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV54707125; called by muse, mutect2, varscan2
- NCAPG | c.2296A>T p.N766Y | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs746347285, COSV52272847; called by muse, mutect2, varscan2
- NCKAP5L | c.3130C>T p.R1044W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs753774229, COSV60134124; called by muse, mutect2, varscan2
- NEFH | c.1514del p.P505Qfs*16 | Frame Shift Del (DEL) | VAF 80/305 reads (26%) | catalogued as rs1569197427; called by mutect2, pindel, varscan2
- NFASC | c.1780G>A p.A594T (on ENST00000339876 / NM_001378329.1; = p.A605T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.744); catalogued as rs781458504, COSV58358918; called by muse, mutect2, varscan2
- NIPAL3 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs767925641, COSV50237816; called by muse, mutect2, varscan2
- NR2C1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs748619839, COSV58012422; called by muse, mutect2, varscan2
- NRK | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 80/345 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs747023598, COSV54589969; called by muse, mutect2, varscan2
- OR5M11 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV73142021; called by muse, mutect2, varscan2
- OSBPL10 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs768880944, COSV67344354; called by muse, mutect2, varscan2
- PADI3 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 67/274 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.086); catalogued as COSV64933980; called by muse, mutect2, varscan2
- PANK2 | c.629-1G>T p.X210_splice | Splice Site (SNP) | VAF 34/136 reads (25%) | catalogued as CS033506, COSV100262007; called by muse, mutect2, varscan2
- PARK7 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 86/362 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs182164240, COSV58580728; called by muse, mutect2, varscan2
- PCDHA12 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.135); catalogued as COSV56547513; called by muse, mutect2, varscan2
- PCLO | c.15188del p.K5063Rfs*2 | Frame Shift Del (DEL) | VAF 68/314 reads (22%) | catalogued as rs1405726136; called by mutect2, pindel, varscan2
- PDE2A | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); catalogued as rs987916591, COSV57813842; called by muse, mutect2, varscan2
- PHC2 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV57108252; called by muse, mutect2, varscan2
- PHF2 | c.2614G>A p.D872N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63683985; called by muse, mutect2, varscan2
- PIK3R4 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.555); catalogued as rs780726079, COSV63241872; called by muse, mutect2, varscan2
- PLA2G2E | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as rs780504394, COSV64290954; called by muse, mutect2, varscan2
- PLCB1 | c.3373G>C p.V1125L | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV62069246; called by muse, mutect2, varscan2
- PLXNB2 | c.5340G>A p.A1780= | Splice Region (SNP) | VAF 37/138 reads (27%) | catalogued as rs372835571; called by muse, mutect2, varscan2
- PNMA2 | c.803A>G p.Y268C | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72908614; called by muse, mutect2, varscan2
- PPFIBP1 | c.1682C>G p.S561C (on ENST00000318304 / NM_177444.3; = p.S555C on NM_003622.4) | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV57298870; called by muse, mutect2, varscan2
- PPIP5K1 | c.4195G>A p.A1399T (on ENST00000396923; = p.A1374T on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs370859351, COSV55812833; called by muse, mutect2, varscan2
- PPP1R12C | c.1110del p.I373Sfs*51 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | catalogued as COSV54738562; called by mutect2, pindel, varscan2
- PRORP | c.1413del p.F471Lfs*30 | Frame Shift Del (DEL) | VAF 111/511 reads (22%) | catalogued as rs766680749; called by mutect2, pindel, varscan2
- PRPF19 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 65/296 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs761083429, COSV57129363; called by muse, mutect2, varscan2
- PTAFR | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV59538411; called by muse, mutect2, varscan2
- PTMS | c.61_63del p.K21del | In Frame Del (DEL) | VAF 151/722 reads (21%) | catalogued as rs973805007; called by pindel, varscan2
- PTPA | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs1389103635, COSV61236500; called by muse, mutect2, varscan2
- PTPN14 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs762664405, COSV65288779; called by muse, mutect2, varscan2
- PTPN21 | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV60852255; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 40/177 reads (23%) | catalogued as rs755727862; called by mutect2, varscan2
- RAB3A | c.66G>A p.M22I | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV55853902; called by muse, mutect2, varscan2
- RAD51AP2 | c.1859del p.N620Ifs*2 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | catalogued as rs754599664, COSV104433747; called by mutect2, pindel, varscan2
- RASAL2 | c.1549C>A p.L517M | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62723857; called by muse, mutect2, varscan2
- RFX1 | c.2599C>T p.R867C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54333707; called by muse, mutect2, varscan2
- RIPOR2 | c.1339T>C p.S447P | Missense Mutation (SNP) | VAF 81/324 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52429505; called by muse, mutect2, varscan2
- RLN2 | c.20dup p.H8Pfs*26 | Frame Shift Ins (INS) | VAF 22/88 reads (25%) | catalogued as rs760343057; called by mutect2, varscan2
- RP1L1 | c.1502A>G p.E501G | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV101222839; called by muse, mutect2
- SATB2 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99610392; called by muse, mutect2
- SEC14L5 | c.723G>A p.M241I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV52042203; called by muse, mutect2, varscan2
- SEMA3G | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as rs745860969, COSV51598603; called by muse, mutect2, varscan2
- SESN1 | c.695C>T p.T232I (on ENST00000356644 / NM_001199933.1; = p.T291I on NM_014454.3) | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs779744842, COSV57422037; called by muse, mutect2, varscan2
- SGSM3 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs1282081724, COSV99960091; called by muse, mutect2
- SIM1 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.37); catalogued as COSV53496942; called by muse, mutect2, varscan2
- SIPA1L1 | c.172del p.R58Efs*8 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | catalogued as rs1567251966; called by mutect2, pindel, varscan2
- SLC17A9 | c.983G>A p.C328Y | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as rs1189467578, COSV64846805, COSV64848434; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 39/182 reads (21%) | catalogued as rs760089491; called by mutect2, varscan2
- SLCO4A1 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV53894261; called by muse, mutect2, varscan2
- SLITRK4 | c.2420G>T p.R807M | Missense Mutation (SNP) | VAF 100/397 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as COSV62026198, COSV62026662; called by muse, mutect2, varscan2
- SMURF1 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.306); catalogued as rs771219258, COSV62816846; called by muse, mutect2, varscan2
- SORL1 | c.4562G>A p.C1521Y | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52763034; called by muse, mutect2, varscan2
- SOX15 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs761527672, COSV51468456; called by mutect2, varscan2
- SOX3 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65168745; called by muse, mutect2, varscan2
- SPAG6 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.204); catalogued as COSV57624170; called by muse, mutect2, varscan2
- SPSB2 | c.451dup p.Q151Pfs*9 | Frame Shift Ins (INS) | VAF 16/74 reads (22%) | catalogued as rs782517836; called by mutect2, pindel, varscan2
- SPTB | c.6004T>G p.W2002G | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV67635160; called by muse, mutect2, varscan2
- SSH2 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 46/612 reads (8%) | catalogued as COSV52172633; called by muse, mutect2
- STAU2 | c.1091dup p.N364Kfs*13 (on ENST00000524300 / NM_001164380.2; = p.N332Kfs*13 on NM_014393.2) | Frame Shift Ins (INS) | VAF 156/647 reads (24%) | catalogued as rs746501298; called by mutect2, varscan2
- STC2 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1480708858, COSV54182305; called by muse, mutect2, varscan2
- STEAP4 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs376035088; called by muse, mutect2, varscan2
- STK24 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs998156740, COSV64823819; called by muse, mutect2, varscan2
- STYXL2 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs374488804; called by muse, mutect2, varscan2
- SVEP1 | c.4649C>T p.A1550V | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.881); catalogued as rs544713872, COSV65690354; called by muse, mutect2, varscan2
- TAF1B | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs377190633; called by muse, mutect2, varscan2
- TBCD | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.388); catalogued as COSV62808031; called by muse, mutect2, varscan2
- TCF20 | c.5876G>A p.R1959Q | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs763374542, COSV59491918; called by muse, mutect2, varscan2
- TCP11L2 | c.158-1G>A p.X53_splice | Splice Site (SNP) | VAF 44/184 reads (24%) | catalogued as COSV54432790; called by muse, mutect2, varscan2
- TEAD4 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1291664123, COSV63282537; called by muse, mutect2, varscan2
- TENM1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 97/408 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64443825; called by muse, mutect2, varscan2
- TET1 | c.843G>C p.K281N | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV65387204, COSV65389773; called by muse, mutect2, varscan2
- TFAM | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV65877304; called by muse, mutect2, varscan2
- THBS4 | c.566T>C p.V189A | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV63471030; called by muse, mutect2, varscan2
- TMEM132D | c.1504G>A p.V502M | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.051); catalogued as rs767934327, COSV67160683; called by muse, mutect2, varscan2
- TMEM177 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs766765864, COSV55609765; called by muse, mutect2, varscan2
- TMEM98 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV55583630; called by muse, mutect2, varscan2
- TOP2A | c.3047T>C p.L1016S | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV101396018, COSV70733956; called by muse, mutect2, varscan2
- TRIOBP | c.2320C>T p.R774* | Nonsense Mutation (SNP) | VAF 227/823 reads (28%) | catalogued as rs529745904, COSV60384642; called by muse, mutect2, varscan2
- TRPM1 | c.3901del p.T1301Pfs*6 | Frame Shift Del (DEL) | VAF 55/243 reads (23%) | catalogued as rs765296730; called by mutect2, pindel, varscan2
- TTN | c.4078G>T p.G1360* (on ENST00000591111; = p.G1314* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 39/222 reads (18%) | catalogued as COSV60360027, COSV60367462; called by muse, mutect2, varscan2
- UBASH3B | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs756434598, COSV52495623; called by muse, mutect2, varscan2
- UFL1 | c.980C>A p.P327H | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as COSV65150739; called by muse, mutect2, varscan2
- UGT1A9 | c.364del p.S122Qfs*12 | Frame Shift Del (DEL) | VAF 99/543 reads (18%) | catalogued as rs773627969; called by mutect2, pindel, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 52/224 reads (23%) | catalogued as rs767420916; called by mutect2, varscan2
- USP15 | c.1285C>T p.R429* (on ENST00000280377 / NM_001351159.2; = p.R400* on NM_006313.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 122/547 reads (22%) | catalogued as COSV54799162; called by muse, mutect2, varscan2
- USP48 | c.770T>A p.L257* | Nonsense Mutation (SNP) | VAF 75/324 reads (23%) | catalogued as COSV57614940; called by muse, mutect2, varscan2
- VCX3B | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1320688244, COSV66843232; called by muse, mutect2, varscan2
- VPS4B | c.502_503insT p.R168Mfs*36 | Frame Shift Ins (INS) | VAF 86/386 reads (22%) | catalogued as COSV99447588; called by mutect2, pindel, varscan2
- VPS8 | c.3748G>C p.G1250R (on ENST00000625842 / NM_001349294.1; = p.G1248R on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54996988; called by muse, mutect2, varscan2
- WASF1 | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 38/480 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100846729; called by muse, mutect2
- WDR20 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as COSV54475310; called by muse, mutect2, varscan2
- WDR44 | c.417del p.K139Nfs*13 | Frame Shift Del (DEL) | VAF 41/166 reads (25%) | catalogued as COSV54162754; called by mutect2, pindel, varscan2
- WWP1 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 124/493 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1043774516, COSV55364357; called by muse, mutect2, varscan2
- XKR7 | c.1419del p.R474Gfs*230 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as COSV73813414; called by mutect2, pindel, varscan2
- XPNPEP2 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV64370387; called by muse, mutect2, varscan2
- ZBTB14 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs776787444, COSV63696886; called by muse, mutect2, varscan2
- ZBTB7C | c.403del p.E135Rfs*87 | Frame Shift Del (DEL) | VAF 98/388 reads (25%) | catalogued as rs747456682, COSV59688820; called by mutect2, varscan2
- ZFP36L1 | c.242del p.S81Cfs*67 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as COSV60544414, COSV60547262; called by mutect2, varscan2
- ZMYND11 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 97/350 reads (28%) | catalogued as COSV59082173; called by muse, mutect2, varscan2
- ZNF439 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376455096; called by muse, mutect2, varscan2
- ZNF770 | c.1230T>G p.F410L | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62545127; called by muse, mutect2, varscan2
- ZNF770 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.345); catalogued as COSV62545134; called by muse, mutect2, varscan2
- ZNRF3 | c.1502C>T p.P501L (on ENST00000544604 / NM_001206998.2; = p.P401L on NM_032173.3) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV60438559; called by muse, mutect2, varscan2
- ZP4 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1258928199, COSV63913533; called by muse, mutect2, varscan2
- A4GALT | c.201del p.T68Pfs*46 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- ABCA5 | c.3234dup p.I1079Yfs*50 | Frame Shift Ins (INS) | VAF 36/212 reads (17%) | called by mutect2, pindel, varscan2
- APOB | c.8538del p.F2846Lfs*28 | Frame Shift Del (DEL) | VAF 64/289 reads (22%) | called by mutect2, pindel, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 31/116 reads (27%) | called by mutect2, pindel, varscan2
- C3P1 | n.2677A>C | Splice Region (SNP) | VAF 60/244 reads (25%) | called by muse, mutect2, varscan2
- CCDC149 | c.729del p.K243Nfs*23 | Frame Shift Del (DEL) | VAF 180/754 reads (24%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 37/124 reads (30%) | called by mutect2, pindel, varscan2
- CHD3 | c.3105del p.V1037Wfs*36 | Frame Shift Del (DEL) | VAF 58/267 reads (22%) | called by mutect2, pindel, varscan2
- CIAO3 | c.953dup p.Y319Lfs*20 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- CPVL | c.1251del p.V418Ffs*24 | Frame Shift Del (DEL) | VAF 60/235 reads (26%) | called by mutect2, varscan2
- CSNK1E | c.510_512del p.N170del | In Frame Del (DEL) | VAF 45/220 reads (20%) | called by mutect2, pindel, varscan2
- DENND2B | c.218del p.P73Qfs*53 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- EEF1AKMT3 | c.566_570dup p.F191Rfs*51 | Frame Shift Ins (INS) | VAF 24/103 reads (23%) | called by mutect2, pindel, varscan2
- EEF2K | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, varscan2
- FAM214A | c.1del p.M1? | Frame Shift Del (DEL) | VAF 50/289 reads (17%) | called by mutect2, pindel, varscan2
- FBN2 | c.8168del p.P2723Lfs*72 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- FOXO4 | c.636del p.K213Rfs*62 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- GPR101 | c.562del p.A188Pfs*18 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- IFNA16 | c.532dup p.S178Ffs*21 | Frame Shift Ins (INS) | VAF 121/529 reads (23%) | called by mutect2, pindel, varscan2
- IGHM | c.1121del p.P374Rfs*5 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- IGHV3-20 | c.83del p.G28Efs*10 | Frame Shift Del (DEL) | VAF 46/240 reads (19%) | called by mutect2, varscan2
- ILKAP | c.1001dup p.E335Rfs*14 | Frame Shift Ins (INS) | VAF 39/175 reads (22%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 102/217 reads (47%) | called by mutect2, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- LRRC41 | c.1034del p.P345Qfs*44 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- MAOB | c.1445del p.L482Wfs*14 | Frame Shift Del (DEL) | VAF 73/342 reads (21%) | called by mutect2, pindel, varscan2
- NSD1 | c.4371del p.F1457Lfs*30 | Frame Shift Del (DEL) | VAF 123/569 reads (22%) | called by mutect2, pindel, varscan2
- PHF3 | c.2978del p.N993Tfs*9 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- PIK3R1 | c.460_461del p.S154Lfs*12 | Frame Shift Del (DEL) | VAF 80/410 reads (20%) | called by pindel, varscan2
- PIK3R1 | c.1325_1357del p.I442_Y452del (on ENST00000521381 / NM_181523.3; = p.I172_Y182del on NM_181504.4) | In Frame Del (DEL) | VAF 48/268 reads (18%) | called by mutect2, pindel
- PLGRKT | c.183del p.F61Lfs*8 | Frame Shift Del (DEL) | VAF 55/260 reads (21%) | called by mutect2, pindel, varscan2
- PPIG | c.285dup p.E96* | Frame Shift Ins (INS) | VAF 66/353 reads (19%) | called by mutect2, pindel, varscan2
- PPP2R5E | c.522del p.K174Nfs*3 | Frame Shift Del (DEL) | VAF 75/355 reads (21%) | called by mutect2, pindel, varscan2
- PRKDC | c.8110del p.R2704Gfs*13 | Frame Shift Del (DEL) | VAF 74/361 reads (20%) | called by mutect2, pindel, varscan2
- PTEN | c.867del p.V290* | Frame Shift Del (DEL) | VAF 77/420 reads (18%) | called by pindel, varscan2*
- RAB15 | c.206_207del p.R69Ifs*20 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | called by pindel, varscan2
- RBBP5 | c.1256del p.P419Hfs*9 | Frame Shift Del (DEL) | VAF 68/346 reads (20%) | called by mutect2, pindel, varscan2
- RBP3 | c.353A>C p.Q118P | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RC3H2 | c.782_783del p.S261Ffs*13 | Frame Shift Del (DEL) | VAF 52/272 reads (19%) | called by pindel, varscan2
- RERE | c.2246del p.P749Qfs*81 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | called by mutect2, pindel, varscan2
- SMAP1 | c.326del p.P109Hfs*26 | Frame Shift Del (DEL) | VAF 53/235 reads (23%) | called by mutect2, pindel, varscan2
- SPEF2 | c.4325_4326del p.K1442Sfs*25 | Frame Shift Del (DEL) | VAF 69/299 reads (23%) | called by mutect2, pindel, varscan2
- TAS2R41 | c.448del p.W150Gfs*2 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | called by mutect2, pindel, varscan2
- TMEM200C | c.365del p.G122Vfs*140 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- TMEM9 | c.440del p.G147Dfs*74 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, varscan2
- TNFRSF1A | c.562dup p.S188Kfs*13 | Frame Shift Ins (INS) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- UBR4 | c.8406del p.M2803Cfs*16 | Frame Shift Del (DEL) | VAF 27/127 reads (21%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.4861dup p.Q1621Pfs*41 | Frame Shift Ins (INS) | VAF 15/81 reads (19%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.3749del p.N1250Ifs*3 | Frame Shift Del (DEL) | VAF 62/288 reads (22%) | called by mutect2, varscan2
- ZNF44 | c.766del p.W256Gfs*34 (on ENST00000356109 / NM_001164276.2; = p.W208Gfs*34 on NM_016264.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 65/305 reads (21%) | called by mutect2, pindel, varscan2
- ADAM17 | c.309C>T p.N103= | Silent (SNP) | VAF 122/520 reads (23%) | catalogued as rs761183996, COSV60401967; called by muse, mutect2, varscan2
- ALKBH2 | c.447T>C p.T149= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as rs767841243, COSV57451659; called by muse, varscan2
- APOB | c.8910A>G p.V2970= | Silent (SNP) | VAF 80/259 reads (31%) | catalogued as COSV51953291; called by muse, mutect2, varscan2
- BHMT | c.597C>T p.G199= | Silent (SNP) | VAF 41/132 reads (31%) | catalogued as rs748661009, COSV57155832; called by muse, varscan2
- CCNJL | c.867G>A p.T289= | Silent (SNP) | VAF 58/183 reads (32%) | catalogued as rs544092120, COSV57444864; called by muse, mutect2, varscan2
- CEP85L | c.888T>C p.T296= | Silent (SNP) | VAF 66/293 reads (23%) | catalogued as COSV62646614; called by muse, mutect2, varscan2
- CEP89 | c.1527A>T p.A509= | Silent (SNP) | VAF 89/364 reads (24%) | catalogued as COSV59867821; called by muse, mutect2, varscan2
- CFAP161 | c.564C>T p.S188= | Silent (SNP) | VAF 47/216 reads (22%) | catalogued as COSV54430361; called by muse, mutect2, varscan2
- CFL1 | c.183C>T p.G61= | Silent (SNP) | VAF 14/252 reads (6%) | catalogued as COSV100353953; called by muse, mutect2
- CHD4 | c.915T>C p.R305= | Silent (SNP) | VAF 87/350 reads (25%) | catalogued as COSV58910975; called by muse, mutect2, varscan2
- CMTM1 | c.486C>T p.P162= (on ENST00000457188 / NM_181269.3; = p.P279= on NM_052999.4) | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99216328; called by muse, mutect2
- CR1 | c.5862G>A p.A1954= | Silent (SNP) | VAF 64/275 reads (23%) | catalogued as rs368138765; called by muse, mutect2, varscan2
- CYP4F11 | c.903G>A p.V301= | Silent (SNP) | VAF 27/152 reads (18%) | catalogued as COSV56129666; called by muse, mutect2, varscan2
- DAPK1 | c.3210G>A p.Q1070= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV63792114; called by muse, mutect2, varscan2
- DBF4B | c.804G>C p.T268= | Silent (SNP) | VAF 62/261 reads (24%) | catalogued as COSV59263938; called by muse, mutect2, varscan2
- DGCR2 | c.513G>A p.Q171= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs764865799, COSV54222558; called by muse, mutect2, varscan2
- DGKQ | c.834C>T p.D278= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs368535395; called by muse, mutect2, varscan2
- DHX38 | c.924G>A p.T308= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as rs747088854, COSV51697246; called by muse, mutect2, varscan2
- DMXL2 | c.7218T>C p.P2406= | Silent (SNP) | VAF 72/273 reads (26%) | catalogued as rs1288684318, COSV51856664; called by muse, mutect2, varscan2
- DNHD1 | c.14049C>T p.P4683= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV54443656; called by muse, mutect2, varscan2
- ENTPD4 | c.1671C>T p.G557= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs751262101, COSV100652576, COSV62269728; called by muse, mutect2, varscan2
- ERICH6 | c.6C>T p.A2= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV55803408; called by muse, mutect2, varscan2
- ESCO2 | c.1083T>C p.N361= | Silent (SNP) | VAF 111/440 reads (25%) | catalogued as COSV59416548; called by muse, mutect2, varscan2
- FAM83B | c.1416C>T p.N472= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV60927040; called by muse, mutect2, varscan2
- GALK1 | c.615C>T p.S205= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as CM124974, COSV56693601; called by muse, mutect2, varscan2
- GPR179 | c.6591G>A p.Q2197= (on ENST00000621958; = p.Q2196= on NM_001004334.4) | Silent (SNP) | VAF 47/182 reads (26%) | called by muse, mutect2, varscan2
- GPR39 | c.1065C>T p.F355= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs975153846, COSV61417624; called by muse, mutect2, varscan2
- GTPBP6 | c.1464C>T p.D488= | Silent (SNP) | VAF 96/378 reads (25%) | catalogued as rs765217365, COSV58205698, COSV58206066; called by muse, mutect2, varscan2
- H2BU1 | c.204T>C p.N68= | Silent (SNP) | VAF 73/252 reads (29%) | catalogued as COSV64210229; called by muse, mutect2, varscan2
- HDAC5 | c.2796T>C p.I932= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV52243916; called by muse, mutect2, varscan2
- HEXB | c.88C>T p.L30= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV54670135; called by muse, mutect2, varscan2
- HK3 | c.1986T>C p.N662= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV52844831; called by muse, mutect2, varscan2
- IFT140 | c.4290A>G p.P1430= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99247921; called by muse, mutect2
- IGHM | c.1275C>T p.T425= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs372559102; called by muse, mutect2, varscan2
- KLF16 | c.423C>T p.S141= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs747019895, COSV51737327; called by muse, mutect2, varscan2
- LRIG1 | c.762C>T p.A254= | Silent (SNP) | VAF 51/226 reads (23%) | catalogued as COSV56248360; called by muse, mutect2, varscan2
- LUZP1 | c.1866A>G p.S622= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as COSV56505403; called by muse, mutect2, varscan2
- MAGI3 | c.468A>G p.P156= | Silent (SNP) | VAF 44/236 reads (19%) | catalogued as COSV56844422; called by muse, mutect2, varscan2
- MED23 | c.898C>T p.L300= | Silent (SNP) | VAF 37/147 reads (25%) | catalogued as COSV63437584; called by muse, mutect2, varscan2
- MMP20 | c.798C>A p.I266= | Silent (SNP) | VAF 72/344 reads (21%) | catalogued as COSV52778379; called by muse, varscan2
- MRC2 | c.2151C>T p.Y717= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs147395975; called by muse, mutect2, varscan2
- MSH2 | c.2172G>A p.T724= | Silent (SNP) | VAF 82/284 reads (29%) | catalogued as rs370636719, COSV51885103; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH8 | c.555C>T p.A185= | Silent (SNP) | VAF 27/431 reads (6%) | catalogued as rs765710469, COSV67964592, COSV67967696; called by muse, mutect2
- NAV1 | c.3933C>T p.R1311= | Silent (SNP) | VAF 13/166 reads (8%) | catalogued as COSV99818019; called by muse, mutect2
- NFATC1 | c.2040C>T p.N680= | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as rs143940628; called by muse, mutect2, varscan2
- NPC1L1 | c.498G>A p.E166= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV56930521; called by muse, mutect2, varscan2
- OPN1SW | c.570C>T p.T190= | Silent (SNP) | VAF 69/282 reads (24%) | catalogued as rs367950991; called by muse, mutect2, varscan2
- ORAI2 | c.525C>T p.P175= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs1172858953, COSV62690563; called by muse, mutect2, varscan2
- OTOF | c.1446C>T p.V482= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs749138873, COSV55520610; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB2 | c.1977G>A p.T659= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2
- PDE3B | c.1170C>T p.F390= | Silent (SNP) | VAF 11/388 reads (3%) | catalogued as COSV56381260; called by muse, mutect2
- PES1 | c.1098T>C p.Y366= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as COSV58829872; called by muse, mutect2, varscan2
- PHF21A | c.1312C>T p.L438= | Silent (SNP) | VAF 109/435 reads (25%) | catalogued as rs938361923, COSV57660109; called by muse, mutect2, varscan2
- PKP4 | c.2226C>T p.C742= | Silent (SNP) | VAF 36/164 reads (22%) | catalogued as rs139331912; called by muse, mutect2, varscan2
- PLEC | c.8988C>T p.H2996= (on ENST00000322810 / NM_201380.4; = p.H2886= on NM_000445.5) | Silent (SNP) | VAF 37/163 reads (23%) | catalogued as rs200012425, COSV59624550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRAMEF8 | c.912G>C p.L304= | Silent (SNP) | VAF 49/303 reads (16%) | called by muse, mutect2, varscan2
- PRMT1 | c.1020C>T p.N340= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs371303762; called by muse, mutect2, varscan2
- PRPF40B | c.1515T>C p.H505= (on ENST00000380281; = p.H499= on NM_012272.3) | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV56061840; called by muse, mutect2, varscan2
- PRPSAP2 | c.843A>G p.A281= | Silent (SNP) | VAF 67/282 reads (24%) | catalogued as COSV52068094; called by muse, mutect2, varscan2
- RAB39A | c.423A>G p.E141= | Silent (SNP) | VAF 64/224 reads (29%) | catalogued as rs1259426758, COSV57695601; called by muse, mutect2, varscan2
- RADIL | c.1308C>T p.P436= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs540883493, COSV68203800; called by muse, mutect2, varscan2
- RAPGEF1 | c.1821G>A p.P607= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs373744692; called by muse, mutect2, varscan2
- RERE | c.3732C>T p.P1244= | Silent (SNP) | VAF 59/230 reads (26%) | catalogued as rs1470302035, COSV61951138; called by muse, mutect2, varscan2
- RIOK3 | c.1341G>A p.S447= | Silent (SNP) | VAF 22/335 reads (7%) | catalogued as rs762402323, COSV100259092; called by muse, mutect2
- RNASE12 | c.27G>A p.L9= | Silent (SNP) | VAF 80/348 reads (23%) | catalogued as COSV60088412; called by muse, mutect2, varscan2
- RNF213 | c.12219G>A p.V4073= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs1479064193, COSV60409454; called by muse, mutect2, varscan2
- RTTN | c.2754G>A p.S918= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as rs539632845, COSV55348647; called by muse, mutect2, varscan2
- SCN4A | c.552C>T p.D184= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs370730079, COSV71127185; called by muse, mutect2, varscan2
- SIGLEC6 | c.642C>A p.T214= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as COSV100585093; called by muse, mutect2
- SLC26A9 | c.1155T>C p.H385= | Silent (SNP) | VAF 77/308 reads (25%) | catalogued as rs1428850771, COSV61605612; called by muse, mutect2, varscan2
- SMS | c.1041T>C p.C347= | Silent (SNP) | VAF 133/577 reads (23%) | catalogued as COSV65115423; called by muse, mutect2, varscan2
- SNF8 | c.618C>T p.T206= | Silent (SNP) | VAF 60/223 reads (27%) | catalogued as rs755759210, COSV51727844; called by muse, mutect2, varscan2
- SRSF4 | c.150T>C p.D50= | Silent (SNP) | VAF 75/299 reads (25%) | catalogued as COSV65695794; called by muse, mutect2, varscan2
- STARD10 | c.339C>T p.D113= | Silent (SNP) | VAF 48/193 reads (25%) | catalogued as rs752048367, COSV58326941; called by muse, mutect2, varscan2
- THBS4 | c.882A>G p.P294= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as rs773673292, COSV63471034; called by muse, mutect2, varscan2
- TMC3 | c.2511G>A p.S837= | Silent (SNP) | VAF 64/219 reads (29%) | catalogued as rs530749986, COSV63923249; called by muse, mutect2, varscan2
- TREX2 | c.282A>G p.L94= (on ENST00000334497; = p.L51= on NM_080701.3) | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs1266764111, COSV57851225; called by muse, mutect2, varscan2
- TRIM67 | c.1908C>T p.D636= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs374485727; called by muse, mutect2, varscan2
- TRPT1 | c.114C>T p.A38= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV54175908; called by muse, mutect2, varscan2
- TTN | c.52854G>A p.A17618= (on ENST00000591111; = p.A10194= on NM_003319.4) | Silent (SNP) | VAF 56/235 reads (24%) | catalogued as rs376930907; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TYRP1 | c.1161A>G p.T387= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as COSV101141117; called by muse, mutect2, varscan2
- USP43 | c.1299G>A p.Q433= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV53307142; called by muse, mutect2, varscan2
- USP47 | c.3747C>T p.S1249= (on ENST00000399455 / NM_001372095.1; = p.S1161= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 99/403 reads (25%) | catalogued as COSV59694731; called by muse, mutect2, varscan2
- YLPM1 | c.2064G>A p.P688= | Silent (SNP) | VAF 82/339 reads (24%) | catalogued as rs749735666, COSV53121086, COSV53122794; called by muse, mutect2, varscan2
- ZFAT | c.741C>T p.Y247= | Silent (SNP) | VAF 66/292 reads (23%) | catalogued as rs767588874, COSV64737523; called by muse, mutect2, varscan2
- ZNF287 | c.1005A>G p.L335= | Silent (SNP) | VAF 40/180 reads (22%) | catalogued as COSV67689146; called by muse, mutect2, varscan2
- ZNF586 | c.337A>C p.R113= | Silent (SNP) | VAF 48/221 reads (22%) | catalogued as COSV66972765; called by muse, mutect2, varscan2
- ZNF662 | c.540T>C p.G180= | Silent (SNP) | VAF 56/210 reads (27%) | catalogued as COSV60241964; called by muse, mutect2, varscan2
- ELMOD1 | c.-86+454C>A | Intron (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99759556, COSV99760291; called by muse, mutect2, varscan2
- GPHN | c.729+1281C>T | Intron (SNP) | VAF 85/347 reads (24%) | catalogued as COSV59493903; called by muse, mutect2, varscan2
- LINC01559 | n.568A>C | RNA (SNP) | VAF 128/493 reads (26%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1094553 del C | 3'Flank (DEL) | VAF 150/743 reads (20%) | called by mutect2, pindel, varscan2
- SSPOP | n.11004C>T | RNA (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100946892; called by muse, mutect2, varscan2
- TRAC | c.*404del | 3'UTR (DEL) | VAF 32/166 reads (19%) | catalogued as rs754035003; called by mutect2, varscan2
